Somatic mutation profile of tumor specimen TARGET-20-PARKHV-09A (aliquot TARGET-20-PARKHV-09A-01D) from TARGET case TARGET-20-PARKHV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.4 years (2,687 days).
Specimen TARGET-20-PARKHV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11465a78-d17e-4945-b94e-a05b4affbffc.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARKHV-14A (Bone Marrow Normal), aliquot TARGET-20-PARKHV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/077a2b1f-bbeb-445a-b097-6b16a6e23427

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.868_870delinsCGTTTCC p.W290Rfs*10 | Frame Shift Ins (INS) | VAF 13/37 reads (35%) | catalogued as COSV51559626; called by pindel, varscan2*
